RC case RC-B65G — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9056d62-e177-451e-b5bb-b678597cd31b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1979; Vital status: Dead; Days to death: 235 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Jamaica.

Diagnoses (5)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants) (the primary disease): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 38.7 years (14,143 days); Year of diagnosis: 2018; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph node, NOS / Lymph Node, Mesenteric / Lymph Node, Para-Aortic / Bone marrow / Leptomeninges / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 5.5 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 2 days; Days to treatment end: 144 days; Number of cycles: 7; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 2 days; Days to treatment end: 144 days; Number of cycles: 7; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lenalidomide; Initial disease status: Progressive Disease; Days to treatment start: 154 days; Days to treatment end: 160 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Dexamethasone + Oxaliplatin; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAX; Days to treatment start: 163 days; Days to treatment end: 163 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Dexamethasone + Interferon; Initial disease status: Progressive Disease; Days to treatment start: 176 days; Days to treatment end: 184 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Pentostatin; Initial disease status: Progressive Disease; Days to treatment start: 203 days; Days to treatment end: 234 days; Treatment outcome: Progressive Disease; Reason treatment ended: Death; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 39.1 years (14,290 days); Days to diagnosis: 147 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 39.2 years (14,305 days); Days to diagnosis: 162 days.
4. Progression (histology not recorded by GDC). Age at diagnosis: 39.2 years (14,319 days); Days to diagnosis: 176 days.
5. Progression (histology not recorded by GDC). Age at diagnosis: 39.3 years (14,338 days); Days to diagnosis: 195 days.

Follow-up (6 entries)
- Days to follow up: 101 days; Disease response: Partial Response.
- Day 147 (progression): Progression or recurrence: Yes; Days to progression: 147 days.
- Day 162 (progression): Progression or recurrence: Yes; Days to progression: 162 days.
- Day 176 (progression): Progression or recurrence: Yes; Days to progression: 176 days.
- Day 195 (progression): Progression or recurrence: Yes; Days to progression: 195 days.
- Day 235 (end of treatment course 1): Disease response: With Tumor; Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Lactate Dehydrogenase 1797 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 83.1 kg; Height: 185 cm; BMI: 24.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 5; Tobacco smoking onset year: 2008.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample RC-B65G-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65G-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
